Surgical pathology report (de-identified scan), TCGA case TCGA-50-5066, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5066-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

The right upper lobe neoplasm is an invasive pleomorphic carcinoma measuring 2.5 cm. Visceral pleural and angiolymphatic invasion are identified. The margins of resection are free of tumor. All lymph nodes sampled show no evidence of metastatic carcinoma. The stage is T2 N0 MX.

PARTS 1

AND 2: LUNG, RIGHT UPPER LOBE BRONCHUS, BIOPSY -
FRAGMENTS OF MIXED SQUAMOUS AND GLANDULAR PAPILLOMA (0.5 CM).

PART 3: LYMPH NODE, SUBCARINAL, BIOPSY -
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 4: LYMPH NODE, RIGHT TRACHEAL BRONCHIAL ANGLE, BIOPSY -
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 5: LYMPH NODE, RIGHT PARATRACHEAL, BIOPSY -
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 6: LYMPH NODE, LEFT TRACHEAL BRONCHIAL ANGLE, BIOPSY -
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 7: LYMPH NODE, SUBINNOMINATE, BIOPSY -
FIVE REACTIVE LYMPH NODES, NO CARCINOMA SEEN.

PART 8: LUNG, POSTERIOR SEGMENT OF RIGHT UPPER LOBE, SEGMENTECTOMY -
A. INVASIVE PLEOMORPHIC CARCINOMA WITH ADENOCARCINOMA, SQUAMOUS CELL CARCINOMA, GIANT CELL CARCINOMA AND SPINDLE CELL CARCINOMA COMPONENTS (2.5 CM).
B. VISCERAL PLEURAL INVASION IDENTIFIED.
C. ANGIOLYMPHATIC INVASION IDENTIFIED.
D. MARGINS OF RESECTION FREE OF TUMOR.
E. STAGE T2 N0 MX.
F. BACKGROUND LUNG SHOWING EMPHYSEMA.

PART 9: LUNG, POSTERIOR SEGMENT OF RIGHT UPPER LOBE, SEGMENTECTOMY -
A. EMPHYSEMA.
B. NO CARCINOMA SEEN.

Source: NCI Genomic Data Commons file a5e41c5b-d000-47f0-a695-efb0cfc3b473 (TCGA-50-5066.E00CB449-F980-4829-A006-32706F041E94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).